Gene-level copy-number profile of tumor specimen AP-5MX6-GX from APOLLO case AP-5MX6, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-5MX6-GX: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba73c80c-027a-427b-9d6b-f68cb8eb692a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-5MX6-3D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d6eff03d-d3ae-43e4-b8ba-91845607ab8b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 40; copy number 2: 5,143; copy number 3: 11,214; copy number 4: 16,692; copy number 5: 14,168; copy number 6: 8,057; copy number 7: 1,066; copy number 8: 741; copy number 9: 84; copy number 10: 105; copy number 11: 599; copy number 12: 71; copy number 13: 44; copy number 14: 2; copy number 15: 61; copy number 16: 14; copy number 17: 31; copy number 18: 142; copy number 19: 3; copy number 20: 20; copy number 22: 34; copy number 26: 11; copy number 27: 45.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,296,162–48,599,436, 12 genes: RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,266 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,259,742–157,677,749, 4 genes, copy number 10 (within-gene range 7–10): VEPH1, PTX3, SLC66A1L, AC084212.1.
- chr3:160,399,274–198,123,232, 656 genes, copy number 10–11 (within-gene range 7–11) (broad region; genes not listed).
- chr5:58,198–1,900,493, 70 genes, copy number 9 (broad region; genes not listed).
- chr7:54,542,325–55,344,958, 14 genes, copy number 9: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr8:76,162,119–81,284,777, 74 genes, copy number 18 (broad region; genes not listed).
- chr8:95,947,781–98,294,393, 38 genes, copy number 18: SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:98,391,401–98,391,514, 1 gene, copy number 18: AP003355.3.
- chr8:98,943,595–102,810,039, 96 genes, copy number 12–17 (broad region; genes not listed).
- chr8:117,794,490–118,906,155, 5 genes, copy number 17: EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35.
- chr8:123,041,968–138,083,657, 204 genes, copy number 10–27 (within-gene range 6–27) (broad region; genes not listed).
- chr8:142,981,738–144,361,286, 88 genes, copy number 15–22 (broad region; genes not listed).
- chr12:74,656,561–75,209,839, 5 genes, copy number 11: AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2.
- chr12:81,868,368–82,515,817, 9 genes, copy number 11: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.
- chr17:38,195,703–38,257,192, 2 genes, copy number 22: NPEPPSP1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
